Gene-level copy-number profile of tumor specimen TCGA-DC-4745-01A from TCGA case TCGA-DC-4745, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 49.2 years (17,958 days).
Specimen TCGA-DC-4745-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.3af998ca-8754-45b4-a014-35164509d86e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DC-4745-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f2331a15-2206-4203-a338-d7d11cf85825

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 3,987; copy number 2: 34,400; copy number 3: 14,264; copy number 4: 4,924; copy number 5: 998; copy number 6: 1,133; copy number 8: 92; copy number 9: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DC-4745-01A-01D-1732-01): tumor purity 0.81, ploidy 2.4, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,380,476–6,395,578, 1 gene: AC006112.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,184 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,271,566–45,664,349, 166 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr6:60,281,444–61,574,402, 8 genes, copy number 5: AC244258.1, GAPDHP41, AL590227.1, AL512427.2, AL512427.1, RBBP4P3, AL356131.1, MTRNR2L9.
- chr6:63,392,222–63,481,876, 4 genes, copy number 6: AL121949.3, AL121949.2, AL121949.1, EEF1B2P5.
- chr7:70,972–57,837,046, 1,078 genes, copy number 6 (broad region; genes not listed).
- chr9:14,475–43,045,120, 776 genes, copy number 5 (broad region; genes not listed).
- chr13:18,467,172–24,321,031, 152 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,911. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
